Somatic mutation profile of tumor specimen TCGA-EE-A3JD-06A (aliquot TCGA-EE-A3JD-06A-11D-A20D-08) from TCGA case TCGA-EE-A3JD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.0 years (25,930 days).
Specimen TCGA-EE-A3JD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1315d5d-496c-450a-ae19-f2d08fd9ff4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3JD-10A (Blood Derived Normal), aliquot TCGA-EE-A3JD-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d5aeb03-8be1-46dc-b681-6e6a57900ab6

The open-access MAF lists 2,221 somatic variants for this specimen: 1,424 protein-altering or splice-affecting, 747 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,303, Silent 747, Nonsense Mutation 84, Splice Site 17, RNA 16, Intron 14, Splice Region 13, 5'UTR 8, 3'Flank 8, Translation Start Site 4, Frame Shift Del 2, 3'UTR 2.

Variants (750 of 2,221; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as rs72552780, CM031114, COSV55934426; ClinVar: pathogenic; called by mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- CFTR | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs397508342, CM024683, COSV50043054; ClinVar: likely pathogenic; called by mutect2, varscan2
- CRNKL1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1057519885, COSV55618331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 32/201 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- RIPPLY2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100859440, COSV63746041; called by muse, mutect2
- ABCA10 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52221062; called by muse, mutect2
- ABCA12 | c.6727A>G p.R2243G (on ENST00000272895 / NM_173076.3; = p.R1925G on NM_015657.3) | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55956466; called by muse, mutect2
- ABCB4 | c.3094G>A p.G1032R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310608536, COSV55934460; called by muse, mutect2, varscan2
- ABCC12 | c.1261C>G p.P421A | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV60913374; called by muse, mutect2
- ABCC12 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV60911882; called by muse, mutect2
- ABCC3 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53320517; called by muse, mutect2, varscan2
- ABHD1 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs776077943, COSV53205703; called by muse, mutect2, varscan2
- ABHD12 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59285244; called by muse, mutect2
- ABR | c.1973C>T p.S658F (on ENST00000302538 / NM_021962.5; = p.S621F on NM_001092.5) | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV52144810; called by muse, mutect2
- ABRA | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); catalogued as COSV61732240; called by muse, mutect2, varscan2
- ACOX1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376105255, COSV53132126; called by muse, mutect2
- ACRBP | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.854); catalogued as COSV57523628; called by muse, mutect2
- ACSBG2 | c.967A>T p.I323F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV53124218; called by muse, mutect2, varscan2
- ACSBG2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs940495531, COSV53124229; called by muse, mutect2
- ACSL5 | c.489T>A p.Y163* (on ENST00000354273; = p.Y219* on NM_016234.3) | Nonsense Mutation (SNP) | VAF 22/187 reads (12%) | catalogued as COSV61130189; called by muse, mutect2, varscan2
- ACSL5 | c.1015G>A p.D339N (on ENST00000354273; = p.D395N on NM_016234.3) | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755535386, COSV61129611, COSV61132190; called by muse, mutect2, varscan2
- ACSL5 | c.1519G>A p.D507N (on ENST00000354273; = p.D563N on NM_016234.3) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.238); catalogued as COSV61130202; called by muse, mutect2
- ACSM2A | c.733G>A p.D245N (on ENST00000219054; = p.D166N on NM_001308169.2) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.783); catalogued as rs1197928623, COSV54584142, COSV99524994; called by muse, mutect2, varscan2
- ACSM2B | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV61657567; called by muse, mutect2, varscan2
- ACTB | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100079634; called by mutect2, varscan2
- ACTB | c.801G>A p.L267= | Splice Region (SNP) | VAF 15/137 reads (11%) | catalogued as COSV100079637; called by mutect2, varscan2
- ADAM28 | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 17/297 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56099860; called by muse, mutect2
- ADAM28 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV56099872; called by muse, mutect2
- ADAM30 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as rs1037978740, COSV65560937; called by muse, mutect2
- ADAM33 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as rs749410575, COSV100597880; called by muse, mutect2, varscan2
- ADAMTS16 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV56986305; called by muse, mutect2
- ADAMTS2 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.029); catalogued as rs1473795363, COSV52372953; called by muse, mutect2
- ADAMTS20 | c.5324C>T p.P1775L | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895564205, COSV67130352; called by muse, mutect2
- ADAMTS20 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV67130358; called by mutect2, varscan2
- ADAMTSL3 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as rs1364350906, COSV54445135; called by muse, mutect2, varscan2
- ADCY1 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52033541; called by muse, mutect2
- ADCY1 | c.2377C>T p.L793F | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV52033551; called by muse, mutect2, varscan2
- ADCY3 | c.3050C>T p.A1017V | Missense Mutation (SNP) | VAF 17/412 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.272); catalogued as rs903113228, COSV53166767; called by muse, mutect2
- ADCY8 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53904787; called by muse, mutect2
- ADCYAP1R1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs267601483, COSV58441747; called by muse, mutect2, varscan2
- ADGRB3 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395406004, COSV65380744; called by muse, mutect2, varscan2
- ADGRB3 | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53235107, COSV53241518; called by muse, mutect2
- ADGRB3 | c.3882G>A p.M1294I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV53241537; called by muse, mutect2, varscan2
- ADGRE1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV51674788, COSV99166046; called by muse, mutect2
- ADGRL2 | c.2059C>T p.P687S (on ENST00000370717 / NM_001366005.1; = p.P674S on NM_012302.4) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs866926691, COSV54664019; called by muse, mutect2, varscan2
- ADGRV1 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67983683; called by muse, mutect2
- ADGRV1 | c.7474C>T p.L2492F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67983689; called by mutect2, varscan2
- ADGRV1 | c.16672G>A p.D5558N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67979556, COSV67994232; called by muse, mutect2, varscan2
- ADH1B | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1271276092, COSV59296025; called by muse, mutect2
- ADH1B | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59296029; called by muse, mutect2
- AGFG2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 16/186 reads (9%) | catalogued as COSV99499322; called by muse, mutect2
- AGL | c.3409C>T p.P1137S | Missense Mutation (SNP) | VAF 57/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54051820; called by muse, mutect2, varscan2
- AGXT2 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs762356643, COSV51485753; called by mutect2, varscan2
- AHNAK | c.10879C>T p.P3627S | Missense Mutation (SNP) | VAF 22/305 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57211435; called by muse, mutect2
- AHNAK2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.187); catalogued as rs776192528, COSV60913729; called by muse, mutect2, varscan2
- AHNAK2 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs374238837, COSV60913733; called by muse, mutect2, varscan2
- AHSG | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 33/372 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1221690609, COSV56607554; called by muse, mutect2
- AHSP | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.08); catalogued as COSV56528861; called by muse, mutect2
- AIF1L | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV55989841; called by muse, mutect2, varscan2
- AKAP13 | c.3295G>A p.G1099S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV63454554; called by muse, mutect2, varscan2
- AKAP3 | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV57415886, COSV57420926; called by muse, mutect2
- AKAP4 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62074237; called by muse, mutect2, varscan2
- AKAP9 | c.9002C>T p.S3001L (on ENST00000359028; = p.S2977L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV62344144; called by muse, mutect2, varscan2
- AKR1B10 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100610257, COSV62055328; called by muse, mutect2
- AKR1C4 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV54123073; called by muse, mutect2, varscan2
- AL121899.2 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs760403495, COSV67350431; called by muse, mutect2, varscan2
- ALDH16A1 | c.2401G>C p.G801R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52618958; called by muse, mutect2
- ALDH18A1 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV64662468; called by muse, mutect2
- ALDH18A1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV64662470; called by muse, mutect2
- ALKBH1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs1343114928, COSV53659498; called by muse, mutect2
- ALOX15 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.637); catalogued as rs1332971804, COSV53397387; called by muse, mutect2
- ALOX15 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV53397407; called by muse, mutect2, varscan2
- ALPK2 | c.6086T>G p.V2029G | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64492426; called by muse, mutect2, varscan2
- ALPK2 | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 25/349 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV64492440; called by muse, mutect2
- ALX1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV57491987; called by muse, mutect2
- AMBN | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV59825929; called by muse, mutect2
- AMPD1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62415794; called by muse, mutect2, varscan2
- ANG | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59012011; called by muse, mutect2
- ANGEL1 | c.1318T>A p.S440T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.68); catalogued as COSV51872891; called by muse, mutect2, varscan2
- ANK3 | c.12824G>A p.G4275E (on ENST00000280772 / NM_001320874.2; = p.G899E on NM_001149.3) | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV55051708; called by muse, mutect2
- ANK3 | c.7372G>A p.G2458R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55054375; called by muse, mutect2, varscan2
- ANKFY1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58916879; called by muse, mutect2
- ANKRD16 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.338); catalogued as COSV51947271; called by muse, mutect2, varscan2
- ANO4 | c.1396G>A p.E466K (on ENST00000392977 / NM_001286615.2; = p.E431K on NM_178826.4) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV54593435; called by muse, mutect2, varscan2
- ANXA7 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV65823362; called by muse, mutect2
- AOAH | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51739730; called by muse, mutect2
- APBA1 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55226373; called by muse, mutect2, varscan2
- APOL3 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV100652077; called by muse, mutect2
- AQP2 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs1014984131, COSV52229951; called by muse, mutect2
- ARAP2 | c.4301G>A p.G1434E | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58285803; called by muse, mutect2
- ARAP3 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1014644445, COSV53350173; called by muse, mutect2
- ARC | c.788A>T p.N263I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100751710; called by muse, mutect2, varscan2
- ARGFX | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV57682150; called by muse, mutect2, varscan2
- ARHGAP21 | c.5261C>T p.S1754F | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV57609767; called by muse, mutect2
- ARHGAP22 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 30/335 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV50939280, COSV99984423; called by muse, mutect2
- ARHGAP35 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 12/178 reads (7%) | catalogued as rs1324454897, COSV68329190; called by muse, mutect2
- ARHGAP36 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV52265981, COSV52270515; called by muse, mutect2, varscan2
- ARHGEF35 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as COSV100967749, COSV65312769; called by muse, mutect2
- ARHGEF5 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV99282835; called by muse, mutect2, varscan2
- ARIH1 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65911380; called by muse, mutect2
- ARPP21 | c.377A>T p.E126V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV51795999; called by muse, mutect2
- ART1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs752333152, COSV51704129; called by muse, mutect2, varscan2
- ASAH2 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272785683; called by muse, mutect2
- ASAP1 | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV63047605; called by muse, mutect2
- ASPM | c.7663A>G p.K2555E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV54128628; called by muse, mutect2, varscan2
- ASTN1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56066983; called by muse, mutect2, varscan2
- ASTN2 | c.2368C>T p.Q790* (on ENST00000313400 / NM_001365069.1; = p.Q739* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 22/136 reads (16%) | catalogued as COSV57771951; called by muse, varscan2
- ASTN2 | c.2218G>A p.E740K (on ENST00000313400 / NM_001365069.1; = p.E689K on NM_014010.5) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57771975; called by muse, varscan2
- ASXL2 | c.247T>G p.L83V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55457726; called by muse, mutect2
- ASXL3 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs1212866279, COSV52478360; called by muse, mutect2
- ASXL3 | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52463865; called by muse, mutect2, varscan2
- ASXL3 | c.5855C>T p.S1952F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV52463886; called by muse, mutect2, varscan2
- ATAD2 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV54880011; called by muse, mutect2
- ATF6B | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV64351726; called by muse, mutect2
- ATF6B | c.1853C>T p.S618F | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100916821; called by muse, varscan2
- ATG2A | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV65966499; called by mutect2, varscan2
- ATP13A4 | c.2941C>T p.L981F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61319335; called by muse, mutect2
- ATP2A2 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875303; called by muse, mutect2
- ATP2A3 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV59228365; called by muse, mutect2, varscan2
- ATP2B2 | c.2506G>A p.E836K (on ENST00000352432; = p.E802K on NM_001683.5) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59492212; called by muse, mutect2
- ATP6V0A1 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV52872577; called by muse, mutect2
- ATP6V0A1 | c.2433G>C p.Q811H (on ENST00000343619 / NM_001378531.1; = p.Q805H on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52872602; called by muse, mutect2
- ATP8B4 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs866255846, COSV52712173; called by muse, mutect2
- ATP8B4 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52713944; called by muse, mutect2
- ATP9A | c.1619A>C p.Q540P | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1359131255, COSV58765660; called by muse, mutect2, varscan2
- ATP9B | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as rs147932692; called by muse, mutect2, varscan2
- ATRN | c.3319C>A p.Q1107K | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV53526901; called by muse, mutect2, varscan2
- ATRNL1 | c.3110G>A p.G1037E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58084448; called by muse, mutect2, varscan2
- ATXN1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs754259000, COSV55214527; called by muse, mutect2
- AZIN2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as COSV53857029; called by muse, mutect2, varscan2
- BCAS3 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 19/171 reads (11%) | catalogued as COSV66772811; called by muse, mutect2, varscan2
- BCL11A | c.2053G>A p.G685R (on ENST00000335712 / NM_001365609.1; = p.G719R on NM_018014.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV59628496; called by muse, mutect2
- BCL11B | c.1679C>T p.S560L (on ENST00000357195 / NM_001282237.2; = p.S489L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as rs1200651928, COSV61735086; called by muse, mutect2
- BCL11B | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV61734277; called by muse, mutect2
- BCL6B | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV53427513; called by muse, mutect2
- BCLAF1 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 19/201 reads (9%) | catalogued as COSV50357510; called by muse, mutect2
- BDKRB2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV60014425; called by muse, mutect2, varscan2
- BHLHE40 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV56575412; called by muse, mutect2
- BIN1 | c.652G>A p.E218K (on ENST00000316724 / NM_001320642.1; = p.E187K on NM_004305.4) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV52117571; called by muse, mutect2
- BMP5 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63702755; called by muse, mutect2
- BMP5 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as rs1396089139, COSV63701194; called by muse, mutect2, varscan2
- BMPER | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.37); catalogued as COSV51816519; called by muse, mutect2
- BMPER | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV51816529; called by muse, mutect2
- BPIFA1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV62824268; called by muse, mutect2
- BPIFC | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as rs746396523, COSV55912062; called by muse, mutect2, varscan2
- BRAF | c.1520C>T p.S507L (on ENST00000288602 / NM_001374244.1; = p.S467L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs867748453, COSV56106484; called by muse, mutect2, varscan2
- BRINP1 | c.1824G>A p.W608* | Nonsense Mutation (SNP) | VAF 31/196 reads (16%) | catalogued as COSV56297934; called by muse, mutect2, varscan2
- BRINP2 | c.1880G>A p.W627* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as COSV64177079; called by muse, mutect2
- BRINP3 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV66521476; called by muse, mutect2, varscan2
- BRPF1 | c.3643T>C p.*1215Rext*9 | Nonstop Mutation (SNP) | VAF 17/164 reads (10%) | catalogued as COSV57352544; called by muse, mutect2, varscan2
- BSDC1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV61981893; called by muse, mutect2, varscan2
- BSN | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV56516519; called by muse, mutect2, varscan2
- BSN | c.4351G>A p.E1451K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV56516527; called by muse, mutect2, varscan2
- BTBD16 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53262387; called by muse, mutect2, varscan2
- C11orf42 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162957930, COSV56410952, COSV56411641; called by muse, mutect2
- C14orf39 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV58781348; called by muse, mutect2, varscan2
- C1RL | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV56924791; called by mutect2, varscan2
- C1orf100 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57372586; called by muse, mutect2
- C1orf127 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV65437073; called by muse, mutect2
- C1orf146 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs192356914, COSV64860267; called by mutect2, varscan2
- C2CD2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs146922306; called by muse, mutect2, varscan2
- C2CD2 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV61599270; called by muse, mutect2, varscan2
- C2orf16 | c.5023C>T p.Q1675* | Nonsense Mutation (SNP) | VAF 20/369 reads (5%) | catalogued as COSV62675103; called by muse, mutect2
- C2orf78 | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68517344; called by muse, mutect2
- C3 | c.3154+1G>A p.X1052_splice | Splice Site (SNP) | VAF 6/71 reads (8%) | catalogued as rs1317480598, COSV55571859; called by muse, mutect2
- C3 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV55571872; called by muse, mutect2, varscan2
- C5orf38 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV57410795; called by muse, mutect2
- C6orf15 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52537849; called by muse, mutect2
- C8A | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | catalogued as COSV100776510, COSV63483769; called by muse, mutect2
- C8A | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63483774; called by muse, mutect2
- CACNA1A | c.4555G>A p.E1519K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100802088, COSV64196136; called by muse, mutect2
- CACNA1B | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53123014; called by muse, mutect2, varscan2
- CACNA1F | c.3506C>T p.P1169L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59904087; called by muse, mutect2
- CACNA1I | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV60806229; called by muse, mutect2
- CACNA1S | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62938823; called by muse, mutect2
- CACNG2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.538); catalogued as COSV55634214; called by muse, mutect2
- CACNG3 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1417412443, COSV50066657; called by muse, mutect2
- CACNG6 | c.611G>A p.S204N (on ENST00000252729 / NM_145814.1; = p.S133N on NM_031897.2) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV53166420; called by muse, mutect2, varscan2
- CAPZA3 | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.22); catalogued as COSV56851741; called by muse, varscan2
- CAPZA3 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.454); catalogued as COSV56848353; called by muse, mutect2, varscan2
- CARMIL3 | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 33/293 reads (11%) | catalogued as COSV57726063; called by muse, mutect2, varscan2
- CASP1 | c.1099G>A p.E367K (on ENST00000436863 / NM_033292.4; = p.E346K on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV52828161; called by muse, mutect2, varscan2
- CATSPERB | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56423395; called by muse, mutect2, varscan2
- CATSPERE | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as COSV63677428; called by muse, mutect2
- CAVIN2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV58423936; called by muse, mutect2
- CBLB | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.007); catalogued as rs1311016924, COSV51425317; called by mutect2, varscan2
- CCDC125 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV101143601; called by muse, mutect2
- CCDC141 | c.4300G>A p.G1434R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55372398, COSV99836852; called by muse, mutect2
- CCDC141 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99836833; called by muse, mutect2, varscan2
- CCDC170 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV53340091; called by muse, mutect2
- CCDC178 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1221655596, COSV55770329; called by muse, mutect2
- CCDC185 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as rs1266201836, COSV64820700; called by muse, mutect2
- CCDC185 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64820707; called by muse, mutect2
- CCDC38 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs774600539, COSV60182884; called by mutect2, varscan2
- CCDC6 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV54056136; called by muse, mutect2
- CCDC60 | c.967A>G p.S323G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV59542975; called by muse, mutect2, varscan2
- CCDC71 | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58910073, COSV58910281; called by muse, mutect2
- CCDC87 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV59578831; called by muse, mutect2
- CCER1 | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62646604; called by muse, mutect2
- CCL24 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); catalogued as rs1442960872, COSV56116191; called by muse, mutect2, varscan2
- CCL26 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV99139140; called by muse, mutect2
- CCNL2 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV68766525; called by muse, mutect2
- CCNQ | c.429+1G>A p.X143_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as rs1557026541, COSV52343827, COSV52344210, COSV52346069; called by muse, mutect2, varscan2
- CCR2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs934480642, COSV52747642; called by muse, mutect2, varscan2
- CCRL2 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV62193452; called by muse, mutect2, varscan2
- CD101 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV56717536; called by muse, varscan2
- CD163 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as COSV63130095, COSV63131656; called by muse, mutect2, varscan2
- CD163L1 | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867081460, COSV58011299; called by muse, mutect2
- CD1C | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV63806251; called by muse, mutect2
- CD1C | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.672); catalogued as COSV100939389; called by muse, mutect2, varscan2
- CD2 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV65644123; called by muse, mutect2, varscan2
- CD200R1L | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV68004140; called by muse, mutect2, varscan2
- CD300LG | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as COSV53223552; called by muse, mutect2, varscan2
- CDC20 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60522021; called by muse, mutect2, varscan2
- CDC42BPA | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62003520; called by muse, mutect2, varscan2
- CDH13 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51812279; called by muse, mutect2
- CDH24 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57460418; called by muse, mutect2
- CDK12 | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV71000374; called by muse, mutect2
- CDK5RAP2 | c.4052C>T p.P1351L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs750886911, COSV100575441, COSV62573706; called by muse, mutect2, varscan2
- CDSN | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV52537855; called by muse, mutect2, varscan2
- CELA1 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53329658; called by muse, mutect2, varscan2
- CELA3B | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 58/634 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs775354482, COSV100448742; called by muse, mutect2
- CENPE | c.2555A>T p.K852I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV54380133; called by muse, mutect2, varscan2
- CEP104 | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as rs372861320; called by mutect2, varscan2
- CEP152 | c.4580C>T p.S1527F (on ENST00000380950 / NM_001194998.2; = p.S1471F on NM_014985.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV57858860; called by muse, mutect2, varscan2
- CEP162 | c.1258A>G p.N420D | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57619352; called by muse, mutect2
- CEP290 | c.5288T>A p.I1763N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58351058; called by muse, mutect2, varscan2
- CERS4 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 60/644 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52165205; called by muse, mutect2
- CERS6 | c.1003-1G>A p.X335_splice | Splice Site (SNP) | VAF 11/114 reads (10%) | catalogued as COSV59829207; called by muse, mutect2
- CFAP299 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1358372499, COSV63876482; called by muse, mutect2
- CFAP54 | c.4909C>T p.Q1637* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | catalogued as rs1200122910, COSV61570385, COSV61576081; called by muse, mutect2
- CFAP61 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55618696, COSV55626859; called by muse, mutect2
- CFAP61 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV55626874; called by muse, mutect2
- CFAP65 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV58560137; called by muse, mutect2
- CFHR5 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as rs1036456666, COSV56820703, COSV56821014; called by muse, mutect2, varscan2
- CFTR | c.51C>T p.F17= | Splice Region (SNP) | VAF 8/102 reads (8%) | catalogued as CD160238, COSV50048863; called by muse, mutect2
- CHAT | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV60323901; called by muse, varscan2
- CHD2 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.841); catalogued as COSV67708391; called by muse, mutect2
- CHODL | c.189T>G p.S63R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.163); catalogued as COSV54732412; called by muse, mutect2
- CHRM1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.125); catalogued as COSV61006591; called by muse, mutect2, varscan2
- CHRM2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV57767767; called by muse, mutect2
- CHRNA2 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1163843254, COSV53557232; called by muse, mutect2
- CHST15 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV100655146; called by muse, mutect2
- CILP | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV56023505; called by muse, mutect2, varscan2
- CILP | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.559); catalogued as COSV56023516; called by mutect2, varscan2
- CLASP1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746501087, COSV55321894; called by muse, mutect2, varscan2
- CLCA4 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99760500; called by muse, mutect2
- CLEC3A | c.355G>A p.E119K (on ENST00000651443; = p.E110K on NM_005752.6) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by mutect2, varscan2
- CLIC2 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58936258; called by muse, mutect2, varscan2
- CNKSR2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV54254348, COSV54259435; called by muse, mutect2, varscan2
- CNKSR2 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV54254368; called by muse, mutect2, varscan2
- CNN1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99372364; called by muse, mutect2, varscan2
- CNOT4 | c.1483G>A p.A495T (on ENST00000315544 / NM_001190848.1; = p.A492T on NM_013316.4) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV100211594; called by muse, mutect2
- CNR1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62986995; called by muse, mutect2, varscan2
- CNR2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65692744; called by muse, mutect2
- CNTNAP2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100673034, COSV62170689; called by muse, mutect2, varscan2
- CNTNAP2 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62170695; called by muse, mutect2
- CNTNAP2 | c.497G>A p.W166* | Nonsense Mutation (SNP) | VAF 12/256 reads (5%) | catalogued as COSV62170701; called by muse, mutect2
- CNTNAP3 | c.3431G>A p.G1144E | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52666640; called by muse, mutect2, varscan2
- CNTNAP5 | c.2810G>A p.G937E | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70482924; called by muse, mutect2, varscan2
- COBL | c.2566T>A p.F856I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99472652; called by muse, mutect2, varscan2
- COL13A1 | c.623G>A p.G208E (on ENST00000398978 / NM_001130103.2; = p.G170E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637627, COSV62569001; called by muse, mutect2
- COL17A1 | c.4301G>A p.G1434E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59829984; called by mutect2, varscan2
- COL17A1 | c.3014G>A p.G1005D | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs752624634, COSV62226424; called by muse, mutect2, varscan2
- COL1A1 | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV56804225; called by muse, mutect2
- COL21A1 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1216579675, COSV55160191; called by muse, mutect2
- COL3A1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV58586215; called by muse, varscan2
- COL4A2 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV64627428; called by muse, mutect2, varscan2
- COL4A3 | c.4172G>A p.G1391D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67414983; called by mutect2, varscan2
- COL4A4 | c.148A>G p.R50G | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV61631426; called by muse, mutect2
- COL5A1 | c.4049C>T p.P1350L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV65668148; called by muse, mutect2, varscan2
- COL5A1 | c.4231G>A p.G1411R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65668154; called by muse, mutect2, varscan2
- COL5A2 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100880342; called by muse, mutect2
- COL5A2 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV100880343; called by muse, mutect2
- COL5A3 | c.3853A>C p.K1285Q | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV53409631; called by muse, mutect2
- COL6A3 | c.2154C>G p.N718K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as rs1212568030, COSV55087160; called by muse, mutect2, varscan2
- COL7A1 | c.5140G>A p.G1714R | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as COSV60394450; called by muse, mutect2, varscan2
- COL7A1 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV60394458; called by muse, mutect2, varscan2
- COL8A1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53733103; called by mutect2, varscan2
- COPS7A | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57526554; called by muse, mutect2, varscan2
- CORO2A | c.1327T>A p.S443T | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV59662976; called by muse, mutect2, varscan2
- CORO7 | c.2626C>T p.R876W | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs374424650; called by muse, mutect2, varscan2
- COX16 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV66302925; called by muse, mutect2
- CPA1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV50569025; called by muse, mutect2
- CPN1 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs202045437; called by muse, mutect2, varscan2
- CPNE1 | c.1601C>T p.A534V (on ENST00000352393; = p.A539V on NM_003915.5) | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs776135002, COSV100468353, COSV58290918; called by muse, mutect2, varscan2
- CPO | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99786499; called by muse, mutect2, varscan2
- CPSF1 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293213443, COSV58233321; called by muse, mutect2
- CPSF6 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57013968; called by muse, mutect2, varscan2
- CRAT | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 26/227 reads (11%) | catalogued as rs750302998, COSV58876813; called by muse, mutect2, varscan2
- CRB1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV66329215; called by muse, mutect2, varscan2
- CREB3 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 21/323 reads (7%) | catalogued as COSV59206779; called by muse, mutect2
- CREBBP | c.798G>A p.K266= | Splice Region (SNP) | VAF 25/203 reads (12%) | catalogued as COSV52120838; called by muse, mutect2, varscan2
- CRHR1 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs779045365, COSV53277850; called by muse, mutect2
- CRIM1 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV54862854; called by muse, mutect2, varscan2
- CRISP2 | c.64A>T p.K22* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as COSV59254317, COSV59256095; called by muse, mutect2
- CRTC1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV58718216; called by muse, mutect2
- CRTC3 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99185679; called by muse, mutect2
- CSF2RB | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV99453885; called by muse, mutect2
- CSMD2 | c.8536C>T p.R2846C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs746915901, COSV53881396; called by mutect2, varscan2
- CSMD2 | c.8156C>T p.P2719L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs753996795, COSV53904771; called by muse, mutect2, varscan2
- CSMD2 | c.3398G>T p.G1133V | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53904828, COSV99595555; called by muse, mutect2, varscan2
- CSMD3 | c.11108T>A p.V3703D (on ENST00000297405 / NM_001363185.1; = p.V3534D on NM_052900.3) | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52159928; called by muse, mutect2, varscan2
- CSMD3 | c.6299G>A p.W2100* (on ENST00000297405 / NM_001363185.1; = p.W1996* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 9/164 reads (5%) | catalogued as COSV52091146, COSV99821314; called by muse, mutect2
- CSMD3 | c.3080C>T p.S1027F (on ENST00000297405 / NM_001363185.1; = p.S923F on NM_052900.3) | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.936); catalogued as COSV52159999; called by muse, mutect2
- CSMD3 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV52160049; called by muse, varscan2
- CSNK1D | c.189G>A p.V63= | Splice Region (SNP) | VAF 28/338 reads (8%) | catalogued as COSV53924013; called by muse, mutect2
- CSRP3 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56389133; called by muse, mutect2
- CTDSPL2 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV52945824; called by muse, mutect2, varscan2
- CTIF | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as COSV56482643; called by muse, mutect2, varscan2
- CTNNA3 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV65574081; called by muse, mutect2, varscan2
- CTNNA3 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375721994; called by mutect2, varscan2
- CTPS2 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV63722245; called by muse, mutect2, varscan2
- CUL9 | c.4633-1G>A p.X1545_splice | Splice Site (SNP) | VAF 39/500 reads (8%) | catalogued as COSV52727800; called by muse, mutect2
- CUX2 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55630033; called by muse, mutect2, varscan2
- CYB561D2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51702595; called by muse, mutect2, varscan2
- CYLC2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1472871675, COSV66336839; called by muse, mutect2, varscan2
- CYP2A13 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.12); catalogued as rs775405942, COSV57837311; called by mutect2, varscan2
- CYP2C8 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs1273845736, COSV64876861; called by muse, mutect2
- CYP4B1 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as COSV54723105; called by muse, mutect2, varscan2
- CYP4F12 | c.86G>A p.W29* | Nonsense Mutation (SNP) | VAF 21/208 reads (10%) | catalogued as COSV61173431; called by muse, mutect2, varscan2
- CYP4F12 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61173455; called by muse, mutect2, varscan2
- CYP4F2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs868834988, COSV50000964; called by muse, mutect2
- CYP4F3 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 45/553 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55409172; called by muse, mutect2
- CYP7B1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866340497, COSV59582915; called by mutect2, varscan2
- CYP8B1 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60226178, COSV60227797; called by muse, mutect2
- CYP8B1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV60226008; called by muse, mutect2, varscan2
- DCAF5 | c.2600C>T p.T867I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100432491; called by muse, mutect2, varscan2
- DCAF5 | c.2599A>G p.T867A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV100432493; called by muse, mutect2
- DCDC1 | c.4270C>T p.R1424C (on ENST00000597505 / NM_001367979.1; = p.R531C on NM_020869.3) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs764255305, COSV57998750; called by mutect2, varscan2
- DCP2 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV66616811; called by muse, mutect2
- DCX | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.053); catalogued as COSV100576444; called by muse, mutect2, varscan2
- DDX31 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60135333; called by muse, mutect2, varscan2
- DDX43 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV64812609; called by muse, mutect2
- DDX60 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV67095181, COSV67096436; called by muse, mutect2
- DEF6 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV57353853; called by muse, mutect2
- DEF6 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV57353862; called by muse, mutect2
- DEFA6 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs868528284, COSV52405942; called by muse, mutect2
- DEFB116 | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV68722039; called by muse, mutect2
- DENND3 | c.1803A>C p.E601D | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV52802159; called by muse, mutect2
- DENND4B | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV63407357; called by muse, mutect2, varscan2
- DEPDC5 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs867743289, COSV56695845; called by muse, mutect2, varscan2
- DHODH | c.1075A>T p.T359S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54661999; called by muse, mutect2
- DHRS9 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777224534, COSV59139655; called by mutect2, varscan2
- DIAPH3 | c.3407T>C p.L1136P | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV64961507; called by mutect2, varscan2
- DISP3 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV53825748; called by muse, mutect2, varscan2
- DISP3 | c.2922T>G p.S974R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.454); catalogued as COSV53825768; called by muse, mutect2, varscan2
- DLGAP3 | c.2545C>T p.Q849* | Nonsense Mutation (SNP) | VAF 51/472 reads (11%) | catalogued as COSV52393465; called by muse, mutect2, varscan2
- DMBT1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV57541492; called by muse, mutect2
- DMBT1 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.832); catalogued as rs1001413004, COSV57541521; called by muse, mutect2, varscan2
- DMBT1 | c.3038C>T p.S1013F (on ENST00000338354 / NM_001377530.1; = p.S514F on NM_004406.3) | Missense Mutation (SNP) | VAF 59/699 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as rs755750716, COSV57541544; called by muse, mutect2
- DMBT1 | c.3517G>A p.G1173R (on ENST00000338354 / NM_001377530.1; = p.G674R on NM_004406.3) | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV57541563; called by muse, mutect2
- DMRT3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs751127991, COSV51903955; called by muse, varscan2
- DNAH11 | c.12485A>C p.E4162A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV60952705; called by muse, mutect2, varscan2
- DNAH17 | c.11551G>A p.G3851S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67752749; called by muse, mutect2
- DNAH3 | c.11272G>A p.E3758K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as rs868191973, COSV54510062; called by muse, mutect2, varscan2
- DNAH3 | c.8263G>A p.E2755K | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759835468, COSV54509344; called by mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, mutect2
- DNAH5 | c.8617G>T p.D2873Y | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99449827; called by muse, mutect2, varscan2
- DNAH7 | c.7895A>T p.K2632I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.629); catalogued as COSV100415227; called by muse, mutect2, varscan2
- DNAH7 | c.7544G>A p.R2515Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs546179605, COSV56761070; called by mutect2, varscan2
- DNAH7 | c.5818C>T p.P1940S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as rs754916836, COSV56761092; called by mutect2, varscan2
- DNAH7 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56761124; called by muse, mutect2
- DNAH8 | c.6988G>A p.G2330R | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59440530; called by muse, mutect2
- DNAH8 | c.13367C>T p.P4456L | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59440615; called by muse, mutect2, varscan2
- DNAH9 | c.1123A>G p.N375D | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.139); catalogued as COSV52346057; called by muse, mutect2
- DNAH9 | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 11/130 reads (8%) | catalogued as COSV52346062; called by muse, mutect2
- DNAI2 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56758229; called by muse, mutect2
- DNAJB4 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66131535; called by muse, mutect2, varscan2
- DNAJC10 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV51137121; called by muse, mutect2
- DNAJC25-GNG10 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.956); catalogued as rs1217466195, COSV65349803; called by muse, mutect2, varscan2
- DNAJC5B | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV52537085; called by muse, mutect2
- DNAJC7 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.155); catalogued as COSV57268675; called by muse, mutect2, varscan2
- DNM1 | c.1982C>T p.T661I | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV57850780; called by muse, mutect2, varscan2
- DNMT1 | c.2354A>G p.D785G | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV61578661; called by muse, mutect2, varscan2
- DNTTIP2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs1246692499, COSV63283876; called by muse, mutect2
- DOCK2 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99912439; called by muse, mutect2
- DOCK7 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs374515298, COSV52003536; called by mutect2, varscan2
- DOCK9 | c.3941C>T p.S1314F (on ENST00000376460 / NM_001366676.2; = p.S1315F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59626364; called by muse, mutect2
- DOK1 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV51207113; called by muse, mutect2, varscan2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2, varscan2
- DPYD | c.3020G>A p.R1007K | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs1324763240, COSV64595586; called by muse, mutect2
- DPYD | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.42); catalogued as COSV100929063; called by muse, mutect2, varscan2
- DPYD | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as CM147507, COSV64595590; called by muse, mutect2, varscan2
- DPYS | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs751818026, COSV60907008; called by muse, mutect2, varscan2
- DRGX | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 21/290 reads (7%) | catalogued as COSV65136115; called by muse, mutect2
- DSC1 | c.746T>A p.F249Y | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV57144639; called by muse, mutect2, varscan2
- DSCAM | c.5963C>T p.S1988F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV68025396; called by muse, mutect2, varscan2
- DSE | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59063294; called by muse, mutect2, varscan2
- DSEL | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs776589023, COSV100025646; called by muse, mutect2, varscan2
- DSG3 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV57125726; called by muse, mutect2, varscan2
- DSG3 | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV57125740; called by muse, mutect2, varscan2
- DSG4 | c.2192G>A p.G731E | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57390844; called by muse, mutect2, varscan2
- DSPP | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV56809803; called by muse, mutect2, varscan2
- DTNBP1 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV59039599; called by muse, mutect2
- DUSP15 | c.214C>T p.H72Y (on ENST00000278979 / NM_001320479.1; = p.H75Y on NM_080611.4) | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54065889; called by muse, mutect2
- DUSP16 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.11); catalogued as COSV53807332, COSV99962963; called by muse, mutect2
- DYSF | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV50301412; called by muse, mutect2, varscan2
- DZIP1 | c.2411G>A p.G804E (on ENST00000347108; = p.G785E on NM_014934.5) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs1016281699, COSV61265333; called by muse, mutect2
- E2F8 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs867022691, COSV51461648; called by muse, mutect2, varscan2
- ECM1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV60872741; called by muse, mutect2
- EFCAB6 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 19/462 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV53061895; called by muse, mutect2
- EFCAB6 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs147806364; called by muse, mutect2, varscan2
- EGFLAM | c.2506G>A p.E836K (on ENST00000354891 / NM_001205301.2; = p.E828K on NM_152403.4) | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV59299371; called by muse, mutect2
- EHBP1L1 | c.4470G>A p.R1490= | Splice Region (SNP) | VAF 11/78 reads (14%) | catalogued as COSV58572546; called by muse, mutect2, varscan2
- EIF4B | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs370487271; called by mutect2, varscan2
- EIF4G3 | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV51675642; called by muse, mutect2, varscan2
- ELAVL4 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV63915537; called by muse, mutect2, varscan2
- ELL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1283382779, COSV52982061; called by muse, mutect2
- ELOA2 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV55297713; called by mutect2, varscan2
- EMILIN3 | c.988T>G p.C330G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1464479489, COSV60035888; called by muse, mutect2
- ENDOU | c.850G>A p.E284K (on ENST00000422538 / NM_001172439.2; = p.E243K on NM_006025.4) | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57464901, COSV57466483; called by muse, mutect2
- EP300 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54331275; called by muse, mutect2, varscan2
- EPG5 | c.4904C>T p.P1635L | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56348458; called by muse, mutect2
- EPHA1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 70/1236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99313983; called by muse, mutect2
- EPHB2 | c.2390C>T p.A797V (on ENST00000400191 / NM_001309193.2; = p.A798V on NM_004442.7) | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV101007018; called by muse, mutect2, varscan2
- EPHB4 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1376373159, COSV62268641; called by muse, mutect2, varscan2
- EPS8 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55529818; called by muse, mutect2
- ERC2 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs866470365, COSV55609221, COSV55611425; called by muse, mutect2
- EREG | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs1424112311, COSV55261204; called by muse, mutect2
- ERF | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV55895629; called by muse, mutect2, varscan2
- ERICH3 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as COSV100444592, COSV58603891; called by muse, mutect2, varscan2
- ERICH3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV58604959, COSV58612597; called by muse, mutect2, varscan2
- ESPNL | c.2682G>A p.W894* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58033959; called by muse, mutect2
- ESRP2 | c.328-1G>A p.X110_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as rs1386209963, COSV52173068; called by muse, mutect2
- ESX1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV101006443; called by muse, mutect2, varscan2
- ESX1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 37/198 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV101006444; called by muse, mutect2, varscan2
- ESYT3 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.076); catalogued as COSV56680224; called by muse, mutect2
- ETV3 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58747949; called by muse, mutect2, varscan2
- EVI5 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100789680; called by muse, mutect2
- EVPL | c.3026C>T p.T1009I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV56909973; called by muse, mutect2
- EVPL | c.2569-1G>A p.X857_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV56909981; called by muse, mutect2, varscan2
- EXOC1 | c.1725-1G>A p.X575_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV62120040; called by muse, mutect2, varscan2
- EYA1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58161154; called by muse, mutect2
- EYA2 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100426824; called by muse, mutect2
- F10 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 31/385 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV65020695; called by muse, mutect2
- F11 | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV53006149; called by muse, varscan2
- F2RL3 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50185415, COSV50187057; called by muse, mutect2
- F8 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs781786650, COSV64272350, COSV64278664; called by muse, mutect2, varscan2
- FAM13C | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377657760, COSV53255715; called by mutect2, varscan2
- FAM155A | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65558931; called by muse, mutect2
- FAM155B | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV52935906; called by muse, mutect2, varscan2
- FAM160A2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1237905124, COSV56410959; called by muse, mutect2, varscan2
- FAM181A | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1158740103, COSV50888261; called by muse, mutect2, varscan2
- FAM47A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV60495968, COSV60498995; called by muse, mutect2, varscan2
- FAM47A | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs769448337, COSV60495012, COSV60495976; called by mutect2, varscan2
- FAM47A | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1381450905, COSV60495984; called by muse, mutect2
- FAM47C | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV63726013; called by muse, mutect2, varscan2
- FAM47C | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1556332120, COSV100792984, COSV63726021; called by muse, mutect2, varscan2
- FAM71B | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV57228720; called by muse, mutect2, varscan2
- FAM83B | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60921479; called by muse, mutect2
- FARP2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50870647; called by muse, mutect2, varscan2
- FASN | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs761357571, COSV60753409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT1 | c.8438C>T p.P2813L | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV71673469; called by muse, mutect2
- FAT3 | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs377153421; called by mutect2, varscan2
- FAT3 | c.6196G>A p.A2066T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53101842; called by muse, mutect2, varscan2
- FAT4 | c.8360C>T p.S2787F | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV58674572; called by muse, mutect2
- FAT4 | c.10420A>G p.T3474A | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58677374, COSV58681090; called by muse, mutect2, varscan2
- FBXO15 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54043050; called by muse, mutect2
- FBXO32 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV71552043; called by muse, mutect2
- FBXO39 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV58621640; called by muse, mutect2
- FBXO42 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1163578836, COSV65045386; called by muse, mutect2, varscan2
- FCGBP | c.8915G>A p.R2972Q | Missense Mutation (SNP) | VAF 40/459 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as rs766301042; called by muse, mutect2
- FCGBP | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs772636030; called by muse, mutect2, varscan2
- FCRL5 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV62511305, COSV62514240; called by muse, mutect2, varscan2
- FER1L6 | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67549498; called by mutect2, varscan2
- FGD6 | c.3414G>A p.M1138I | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59692546; called by muse, mutect2, varscan2
- FGF6 | c.506A>T p.N169I | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57403768; called by muse, mutect2
- FGFBP2 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as COSV52587844; called by muse, mutect2
- FGFR2 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1251168391, COSV60645397; called by muse, mutect2
- FHDC1 | c.153G>C p.R51S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV52599280; called by muse, mutect2, varscan2
- FKBP6 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs1216896736, COSV52719022; called by muse, mutect2, varscan2
- FLG | c.10747G>A p.E3583K | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as rs144652887; called by muse, varscan2
- FLG | c.10442G>A p.G3481E | Missense Mutation (SNP) | VAF 49/687 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64240689, COSV64250158; called by muse, mutect2
- FLG | c.10076G>A p.G3359E | Missense Mutation (SNP) | VAF 34/899 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV64240693; called by muse, mutect2
- FLG | c.7526G>A p.G2509E | Missense Mutation (SNP) | VAF 59/697 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs775311965, COSV64240697; called by muse, mutect2
- FLG | c.4025C>T p.A1342V | Missense Mutation (SNP) | VAF 84/784 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.514); catalogued as COSV64237025; called by muse, mutect2, varscan2
- FLG | c.3822T>G p.S1274R | Missense Mutation (SNP) | VAF 43/415 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs1201806085, COSV100911587; called by muse, mutect2, varscan2
- FLG | c.3821G>A p.S1274N | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100911588; called by muse, mutect2, varscan2
- FLNC | c.4289G>A p.G1430E | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57967194; called by muse, mutect2
- FLNC | c.4290G>A p.G1430= | Splice Region (SNP) | VAF 11/195 reads (6%) | catalogued as rs1387109130, COSV100368113; called by muse, mutect2
- FLT3 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54060207; called by muse, mutect2
- FLT3 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as COSV54047622; called by muse, mutect2, varscan2
- FMO3 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV63006289, COSV63006997; called by mutect2, varscan2
- FMO5 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.117); catalogued as rs143729816; called by muse, mutect2
- FMOD | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV61609916; called by muse, mutect2, varscan2
- FNDC1 | c.3538G>A p.D1180N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV51943229; called by mutect2, varscan2
- FOXD4L3 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs1371130320, COSV61551361; called by muse, mutect2
- FRAS1 | c.3510G>A p.W1170* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as rs867107569, COSV53605305; called by muse, mutect2
- FRMPD4 | c.3782C>T p.S1261L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV66213952; called by muse, mutect2, varscan2
- FSIP2 | c.16949G>A p.R5650Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1372238930, COSV58083776; called by muse, mutect2
- FSIP2 | c.20618G>A p.G6873E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58083792; called by muse, mutect2, varscan2
- FST | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56815477; called by muse, mutect2
- FTHL17 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV63266778, COSV63267286; called by muse, mutect2, varscan2
- FUCA1 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs775609474, COSV65699022; called by muse, mutect2, varscan2
- GABRA1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50102622; called by mutect2, varscan2
- GABRB3 | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 15/286 reads (5%) | catalogued as COSV54660872; called by muse, mutect2
- GABRB3 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54660902; called by muse, mutect2
- GABRE | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64818853; called by muse, mutect2, varscan2
- GABRG1 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV54952975; called by mutect2, varscan2
- GALNT18 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV99924628; called by muse, mutect2
- GALNT18 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.5); catalogued as rs1223899644, COSV57148118; called by muse, mutect2, varscan2
- GALNT6 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV62542024; called by muse, mutect2, varscan2
- GAN | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs748209210, COSV73720855; ClinVar: uncertain significance; called by muse, mutect2
- GATM | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67540300; called by muse, varscan2
- GBA3 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV72438049; called by muse, mutect2
- GBP6 | c.1852G>A p.G618S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV65011284; called by muse, mutect2, varscan2
- GBP7 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54009313; called by muse, mutect2, varscan2
- GBP7 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV54009320; called by muse, mutect2, varscan2
- GCK | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60786649; called by muse, mutect2
- GCM2 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as COSV65275094; called by muse, mutect2
- GCNT4 | c.660G>A p.W220* | Nonsense Mutation (SNP) | VAF 11/130 reads (8%) | catalogued as COSV59280756; called by muse, mutect2
- GDA | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865863910, COSV52992270; called by muse, mutect2, varscan2
- GDA | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV52992291; called by muse, mutect2
- GFM1 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV51832242; called by muse, mutect2, varscan2
- GGNBP2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs755452058; called by muse, mutect2
- GHR | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV50110802; called by muse, mutect2, varscan2
- GHR | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867392523, COSV50109830, COSV50135382; called by muse, mutect2
- GJA8 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV53788670; called by muse, mutect2
- GJC1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57911093; called by muse, mutect2
- GLP1R | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs1415707619, COSV100952575, COSV64714810; called by muse, mutect2, varscan2
- GLRA4 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV60327525; called by muse, mutect2, varscan2
- GNAZ | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs1253604242, COSV50736897; called by muse, mutect2, varscan2
- GNB4 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51709250; called by muse, mutect2, varscan2
- GPC3 | c.1658A>C p.H553P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as COSV63662924; called by muse, varscan2
- GPC5 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV65592934; called by muse, mutect2
- GPER1 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.682); catalogued as rs1162032137, COSV52468686; called by muse, mutect2, varscan2
- GPR119 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV52275521; called by muse, mutect2, varscan2
- GPR142 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV59519152; called by muse, mutect2, varscan2
- GPR149 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67666952; called by muse, mutect2, varscan2
- GPR158 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV66268815; called by muse, mutect2
- GPR171 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56376427; called by muse, mutect2, varscan2
- GPR4 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59916573; called by muse, mutect2, varscan2
- GPR50 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV54437487; called by muse, mutect2, varscan2
- GPR50 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54436636; called by muse, mutect2, varscan2
- GPR6 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51571678; called by muse, mutect2, varscan2
- GRHL2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52548521; called by muse, mutect2
- GRIK2 | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.879); catalogued as COSV59730284; called by muse, mutect2
- GRIK3 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs746494649, COSV66138660; called by muse, varscan2
- GRIK3 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66138670; called by muse, mutect2, varscan2
- GRIK4 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 22/417 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.403); catalogued as COSV70801841; called by muse, mutect2
- GRIN2A | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs1309428568, COSV100410628, COSV58059641; called by muse, varscan2
- GRIN2D | c.1581G>A p.E527= | Splice Region (SNP) | VAF 16/144 reads (11%) | catalogued as COSV54378357; called by muse, mutect2
- GRK1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1238355634, COSV59552545; called by muse, mutect2, varscan2
- GRM2 | c.1795A>G p.K599E | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1207289934, COSV56584469; called by muse, mutect2
- GRM4 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65212627; called by muse, mutect2
- GRM8 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV58820387, COSV58853973; called by muse, mutect2, varscan2
- GRM8 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1454348314, COSV58820398; called by muse, mutect2, varscan2
- GSTM3 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV56662006; called by muse, mutect2
- GTPBP1 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs750227225, COSV53284284; called by muse, mutect2, varscan2
- H2AC1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV51237144; called by muse, mutect2
- HCRTR2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866684522, COSV63795299; called by muse, mutect2, varscan2
- HDAC9 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1042313151, COSV101286773; called by muse, mutect2, varscan2
- HEATR3 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs764222969, COSV53529008; called by mutect2, varscan2
- HELLS | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs781780355, COSV53295365; called by mutect2, varscan2
- HERC1 | c.13136C>T p.P4379L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770061334, COSV71247382; called by mutect2, varscan2
- HERC2 | c.12266G>A p.R4089K | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV55319826; called by muse, mutect2
- HERC2 | c.10454C>T p.T3485I | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.979); catalogued as COSV55319864; called by muse, mutect2, varscan2
- HERC2 | c.5716G>T p.V1906F | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55319883; called by muse, mutect2
- HGF | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.711); catalogued as rs865828369, COSV99737024; called by muse, mutect2
- HHLA2 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63315449; called by mutect2, varscan2
- HHLA2 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as rs201761554, COSV63316858; called by mutect2, varscan2
- HIF3A | c.994G>A p.E332K (on ENST00000377670 / NM_152795.4; = p.E263K on NM_022462.4) | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV52197654; called by muse, mutect2
- HIP1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV61185203; called by muse, mutect2, varscan2
- HIVEP3 | c.6073C>T p.P2025S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1252084537, COSV99912625; called by muse, mutect2, varscan2
- HIVEP3 | c.3665C>T p.S1222F | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.862); catalogued as rs1225242220, COSV56014025; called by muse, mutect2
- HJV | c.986G>A p.R329Q (on ENST00000336751 / NM_213653.4; = p.R216Q on NM_145277.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs782614415, COSV60951119; called by muse, mutect2, varscan2
- HLA-DQB1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs9273943, COSV66569418; called by muse, mutect2, varscan2
- HMGCL | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs764665830, COSV52525674; called by muse, mutect2, varscan2
- HOOK1 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs1432894976, COSV100969101; called by muse, mutect2, varscan2
- HOXB1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53317037; called by muse, mutect2
- HOXD10 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1242039610, COSV50891362; called by muse, mutect2, varscan2
- HSD17B14 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs908362279, COSV54413155, COSV99622676; called by muse, mutect2, varscan2
- HSD3B1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.424); catalogued as COSV52490359; called by muse, mutect2
- HSPA12A | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV65021954; called by muse, mutect2
- HTR1F | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758773315, COSV60389477; called by mutect2, varscan2
- HTR3E | c.832C>T p.R278C (on ENST00000415389 / NM_001256613.1; = p.R293C on NM_182589.2) | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs746823917, COSV58946547; called by muse, mutect2, varscan2
- HTR4 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58793702; called by muse, mutect2
- HYAL4 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56138360; called by muse, mutect2, varscan2
- HYDIN | c.4930C>T p.R1644C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs993703682, COSV59255296; called by muse, mutect2
- HYDIN | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55483153; called by muse, mutect2, varscan2
- ICE1 | c.5626C>T p.P1876S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV56823099; called by muse, mutect2, varscan2
- IFT46 | c.310C>T p.P104S (on ENST00000264021 / NM_001168618.2; = p.P155S on NM_020153.3) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50594199, COSV50594396; called by muse, mutect2
- IGDCC4 | c.2405C>T p.T802I | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs768248896, COSV61536421; called by mutect2, varscan2
- IGHV3-53 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as rs782319371; called by muse, mutect2
- IGHV6-1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as rs543799892; called by muse, mutect2, varscan2
- IGKV1-17 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs760401939; called by muse, mutect2, varscan2
- IGLV3-12 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs374794587; called by mutect2, varscan2
- IGSF1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV63837100; called by muse, mutect2, varscan2
- IL12RB1 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1568514893, COSV59096913; called by muse, mutect2
- IL17A | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1208310869, COSV60684303; called by muse, mutect2, varscan2
- IL17RD | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV56337259; called by muse, mutect2, varscan2
- IL21R | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV61969881; called by muse, mutect2
- IL7R | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV57407784; called by muse, mutect2, varscan2
- ILDR2 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54830365; called by muse, mutect2, varscan2
- INAVA | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs761732608, COSV66256390; called by muse, mutect2
- ING4 | c.710+2T>C p.X237_splice (on ENST00000396807 / NM_001127582.2; = p.X236_splice on NM_016162.4) | Splice Site (SNP) | VAF 19/128 reads (15%) | catalogued as COSV57523634; called by muse, mutect2, varscan2
- INTS11 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.21); catalogued as COSV60088056; called by muse, mutect2, varscan2
- INTS2 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 18/259 reads (7%) | catalogued as COSV52152593, COSV52152799; called by muse, mutect2
- INTU | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58870993; called by muse, mutect2, varscan2
- IQCD | c.1297G>A p.D433N (on ENST00000416617 / NM_001330452.2; = p.D331N on NM_138451.3) | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.04); catalogued as rs1195703505, COSV55321226; called by muse, mutect2
- IQCH | c.2843G>A p.R948K | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV60051719; called by muse, mutect2
- IQGAP1 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV51584136; called by muse, mutect2, varscan2
- IRAG2 | c.3566G>A p.R1189Q (on ENST00000636465; = p.R234Q on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs751560656, COSV63138483; called by mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, varscan2
- ITCH | c.2117C>T p.S706F (on ENST00000262650 / NM_001257137.3; = p.S665F on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs867531441, COSV52930211, COSV52931337; called by muse, mutect2, varscan2
- ITGA10 | c.2008G>A p.G670S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as COSV65197047; called by muse, mutect2
- ITGA2 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.682); catalogued as COSV56858880; called by muse, mutect2, varscan2
- ITGA8 | c.756A>T p.E252D | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65227692; called by muse, mutect2
- ITGB2 | c.2171A>G p.N724S (on ENST00000302347; = p.N700S on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1487013287, COSV56609159; called by muse, mutect2
- ITGB4 | c.5341C>G p.L1781V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV52324774; called by muse, mutect2, varscan2
- ITGB5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1412981929, COSV56148511; called by muse, mutect2, varscan2
- ITIH1 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV56254313; called by muse, mutect2
- ITIH1 | c.1837G>A p.G613S | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as rs1056450479, COSV56254322; called by muse, mutect2, varscan2
- ITPR1 | c.1300C>T p.P434S (on ENST00000354582; = p.P419S on NM_002222.7) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.999); catalogued as COSV56978237; called by muse, mutect2, varscan2
- IWS1 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54867950; called by muse, mutect2
- IZUMO1 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV55804139; called by muse, mutect2
- JAKMIP1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 33/434 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV51528453; called by muse, mutect2
- KANK2 | c.1535C>T p.S512F (on ENST00000586659 / NM_001379562.1; = p.S520F on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62006511; called by muse, mutect2, varscan2
- KANK4 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV62986374; called by muse, mutect2, varscan2
- KBTBD12 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561962783, COSV59679030; called by mutect2, varscan2
- KCNA5 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV52905287; called by mutect2, varscan2
- KCNA6 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.026); catalogued as COSV54974894; called by muse, mutect2, varscan2
- KCNA6 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54973912, COSV54974904; called by muse, mutect2, varscan2
- KCND2 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs767027587, COSV58577133; called by mutect2, varscan2
- KCNE1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs199473350, CM056968, COSV61606438; ClinVar: not provided / uncertain significance; called by mutect2, varscan2
- KCNE2 | c.148A>C p.I50L | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51710220; called by muse, mutect2, varscan2
- KCNH2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs746600107, COSV51138385; ClinVar: uncertain significance; called by muse, varscan2
- KCNH6 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV59002774; called by muse, mutect2
- KCNH7 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59794391, COSV59795868, COSV59810588; called by muse, mutect2
- KCNJ4 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.925); catalogued as rs1478224744, COSV57856828; called by muse, mutect2, varscan2
- KCNJ6 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55711857, COSV99900450; called by muse, mutect2
- KCNMA1 | c.3052G>A p.D1018N (on ENST00000286628 / NM_001161352.2; = p.D960N on NM_002247.4) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV54227483; called by muse, mutect2, varscan2
- KCNQ2 | c.391A>T p.I131F | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.932); catalogued as COSV60433324; called by muse, mutect2
- KCNS2 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV54638208; called by muse, mutect2
- KCNT1 | c.945G>A p.M315I (on ENST00000488444; = p.M334I on NM_020822.3) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV53700077; called by muse, mutect2, varscan2
- KCTD19 | c.2735G>A p.R912K | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58572411; called by muse, mutect2
- KDM2A | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs772171917, COSV67081821; called by mutect2, varscan2
- KDM2A | c.2869C>T p.L957F | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1565427865, COSV58189359; called by muse, mutect2
- KDM5A | c.1774-1G>A p.X592_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV66991920; called by muse, mutect2, varscan2
- KIAA0319 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as COSV65497875; called by mutect2, varscan2
- KIAA1549 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs759129177, COSV54312065; called by mutect2, varscan2
- KIF13B | c.3149G>A p.C1050Y | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs1241710070, COSV72954338; called by muse, mutect2
- KIF14 | c.3885C>T p.N1295= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as rs866773363, COSV66261360; called by muse, mutect2, varscan2
- KIF16B | c.2893C>T p.Q965* | Nonsense Mutation (SNP) | VAF 11/171 reads (6%) | catalogued as COSV61703754, COSV61705217; called by muse, mutect2
- KIR3DL2 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as rs763892520, COSV54391202; called by muse, mutect2, varscan2
- KL | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV66308550; called by muse, mutect2, varscan2
- KLF4 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1221024853, COSV65928858; called by muse, mutect2
- KLHDC7A | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs764395980, COSV68769569; called by muse, varscan2
- KLHL18 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.097); catalogued as COSV51745126; called by muse, mutect2
- KLHL7 | c.1684C>T p.R562C (on ENST00000339077 / NM_001031710.3; = p.R514C on NM_018846.5) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV59161084; called by muse, mutect2
- KLK9 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as COSV51590855; called by muse, mutect2, varscan2
- KLRC4 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV58671828; called by muse, mutect2
- KLRD1 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV60273521; called by muse, mutect2, varscan2
- KRT15 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 56/762 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.681); catalogued as COSV54179111; called by muse, mutect2
- KRT23 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as COSV52927550; called by muse, mutect2
- KRT27 | c.1321A>T p.T441S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56971557, COSV56973827; called by muse, mutect2
- KRT3 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs756859222, COSV58815348; called by mutect2, varscan2
- KRT35 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV55842829, COSV99877955; called by muse, mutect2
- KRT39 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.101); catalogued as COSV62917130; called by muse, mutect2, varscan2
- KRT76 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs868612460, COSV60119958; called by muse, mutect2
- KRTAP17-1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | PolyPhen benign (0.347); catalogued as rs76002044, COSV61972111, COSV61972387; called by muse, mutect2
- KRTAP4-4 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66811239; called by muse, mutect2
- KRTAP5-3 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs756859512, COSV68790665; called by muse, mutect2, varscan2
- KSR2 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs866186995, COSV56670934; called by muse, mutect2
- KSR2 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56670955; called by muse, mutect2
- LACTB2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as COSV52567634; called by muse, mutect2, varscan2
- LALBA | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV56395646, COSV56395748; called by muse, mutect2, varscan2
- LAMA3 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58067256; called by muse, mutect2
- LAMA4 | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV57895670, COSV57898269; called by muse, mutect2
- LAMB4 | c.3686G>A p.R1229K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52717732; called by muse, mutect2
- LAMP5 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55715900; called by muse, mutect2
- LELP1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64202405; called by muse, mutect2
- LGALS12 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1049643617, COSV55370006; called by muse, mutect2, varscan2
- LGI2 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101180832; called by muse, mutect2
- LIFR | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1187288698, COSV54688791; called by muse, mutect2
- LILRB4 | c.1310C>T p.P437L (on ENST00000391733 / NM_001278428.3; = p.P436L on NM_001278426.3) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV54404704, COSV99554071; called by muse, mutect2
- LILRB5 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs778979385, COSV60256786; called by muse, mutect2, varscan2
- LIPA | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV60328887; called by muse, mutect2
- LLGL1 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV57497566; called by muse, mutect2, varscan2
- LMO7 | c.4187C>T p.S1396L (on ENST00000357063; = p.S1077L on NM_005358.5) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs964080367, COSV58534555; called by muse, mutect2
- LRP1B | c.5975C>T p.S1992F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67209148; called by muse, mutect2, varscan2
- LRP2 | c.12851T>C p.L4284S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV55550306; called by muse, mutect2, varscan2
- LRRC31 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs140441511, COSV52983485; called by mutect2, varscan2
- LRRC3B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as rs865841768, COSV67520179, COSV67522722; called by mutect2, varscan2
- LRRC4C | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53421311, COSV53423488; called by muse, mutect2
- LRRC58 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55230009; called by muse, mutect2, varscan2
- LRRC7 | c.2207G>A p.G736E (on ENST00000651989 / NM_001370785.2; = p.G703E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV50444361; called by muse, mutect2, varscan2
- LRRC74A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV53609233; called by muse, mutect2, varscan2
- LRRCC1 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64483237; called by muse, mutect2, varscan2
- LRRN3 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57818188, COSV57818741; called by muse, mutect2, varscan2
- LRRTM4 | c.1696G>A p.G566S | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101298563, COSV69159638; called by muse, mutect2, varscan2
- LRRTM4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139560, COSV69139830; called by muse, mutect2, varscan2
- LUZP4 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV64218738; called by muse, mutect2, varscan2
- MAGEB10 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV63311018; called by muse, mutect2, varscan2
- MAGEC1 | c.1414G>A p.G472S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs957937203, COSV53571592, COSV99595689; called by muse, mutect2, varscan2
- MAGEC1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs866448898, COSV53567920; called by muse, mutect2, varscan2
- MAGEE1 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63909846; called by muse, mutect2, varscan2
- MAML1 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV52984712; called by muse, mutect2
- MAML2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV73263248; called by muse, mutect2
- MAN1A1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1213082733, COSV63781141, COSV63783109; called by muse, mutect2, varscan2
- MAP3K21 | c.2206G>A p.G736R | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64041539; called by muse, mutect2
- MAP7D3 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV60170717; called by muse, mutect2, varscan2
- MAPK9 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV58121368; called by muse, mutect2
- MARCHF8 | c.747T>G p.I249M | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60571891; called by muse, mutect2
- MARK1 | c.633C>G p.N211K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV65067069; called by muse, mutect2, varscan2
- MAU2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53234953; called by muse, mutect2
- MCM2 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 62/633 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV54033258; called by muse, mutect2
- MDH2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1554587467, COSV59884060; called by muse, mutect2
- MED12 | c.5432C>T p.P1811L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.077); catalogued as COSV61337730; called by muse, mutect2, varscan2
- MED15 | c.1348C>T p.P450S (on ENST00000263205 / NM_001003891.3; = p.P410S on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1334518207, COSV53028765; called by muse, mutect2, varscan2
- MFSD14B | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64700728; called by muse, mutect2, varscan2
- MGAM | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV71885323; called by muse, mutect2, varscan2
- MGAM | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV71885324; called by muse, mutect2, varscan2
- MGAM | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs749121609, COSV72073544; called by muse, varscan2
- MGAM | c.3704G>T p.R1235L | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV72074499, COSV72075046; called by muse, varscan2
- MGAM | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV72074500; called by muse, varscan2
- MGAM | c.4984G>A p.V1662I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs757615356, COSV72074502; called by muse, varscan2
- MGMT | c.116A>G p.K39R (on ENST00000306010; = p.K8R on NM_002412.5) | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV60025689; called by muse, mutect2
- MGST1 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV50566621; called by mutect2, varscan2
- MIB2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs767289013, COSV61755606; called by muse, mutect2, varscan2
- MICAL1 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62193143; called by muse, mutect2, varscan2
- MICAL2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1257869145, COSV56319570; called by muse, mutect2
- MICAL2 | c.5272A>G p.T1758A | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.145); catalogued as COSV56285576; called by muse, mutect2
- MIEF1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs867109910, COSV100307593, COSV57478660; called by muse, mutect2, varscan2
- MKI67 | c.6316C>T p.P2106S | Missense Mutation (SNP) | VAF 46/504 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.551); catalogued as rs375832658; called by muse, mutect2
- MKX | c.597A>T p.K199N | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV65392005; called by muse, mutect2, varscan2
- MLIP | c.164T>A p.F55Y | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV51428927; called by muse, mutect2
- MMP14 | c.1006T>C p.F336L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100314111; called by muse, mutect2, varscan2
- MMRN2 | c.2707G>A p.G903R | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64400674; called by muse, mutect2
- MOCS1 | c.1205G>A p.W402* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | catalogued as COSV51310922; called by muse, mutect2
- MOG | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65321031; called by muse, mutect2
- MORC1 | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51718554; called by muse, mutect2, varscan2
- MORF4L1 | c.797T>C p.V266A (on ENST00000331268 / NM_206839.2; = p.V227A on NM_006791.4) | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as COSV58704294; called by muse, mutect2
- MPL | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs1339501124, COSV65244655; called by muse, mutect2, varscan2
- MPP6 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as COSV56037535; called by muse, mutect2, varscan2
- MPP7 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.088); catalogued as rs773033463, COSV61731654; called by muse, mutect2, varscan2
- MPPED2 | c.24A>C p.Q8H | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63897744; called by muse, mutect2, varscan2
- MROH7 | c.3553T>C p.C1185R | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59871137; called by muse, mutect2, varscan2
- MRPL21 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs1016987919, COSV54821862; called by muse, mutect2, varscan2
- MRTFA | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs867777031, COSV62932817; called by muse, mutect2
- MS4A3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV53935800, COSV99614507; called by muse, mutect2
- MSH5 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs200847013, COSV65209432; called by muse, mutect2
- MSR1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs866116143, COSV50510106; called by muse, mutect2
- MSRB3 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV57590571; called by muse, mutect2, varscan2
- MSTN | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs761832176, COSV53620798; called by muse, mutect2, varscan2
- MUC1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs771925604, COSV58113174; called by mutect2, varscan2
- MUC13 | c.1038C>G p.C346W | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60699180; called by muse, mutect2, varscan2
- MUC16 | c.32626G>A p.G10876R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as COSV67461443, COSV67494214; called by muse, mutect2, varscan2
1,471 further variants in this file (674 protein-altering or splice-affecting, 747 silent, 50 other) are not listed here.
